CCDI case PBBJZE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e1f25bbf-7055-433a-9ecd-b6f1ce6f9495

Demographics
Sex at birth: male; Race: american indian or alaska native.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.9 years (2,887 days).

Biospecimens (4 samples)
- Sample 0DAEHD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAEHF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DAEHP, 0DAVLX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
